Somatic mutation profile of tumor specimen TCGA-VR-A8Q7-01A (aliquot TCGA-VR-A8Q7-01A-11D-A37C-09) from TCGA case TCGA-VR-A8Q7, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.6 years (22,149 days).
Specimen TCGA-VR-A8Q7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8a514f5-52f7-49f6-893d-2e1d9c3f2fbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8Q7-10A (Blood Derived Normal), aliquot TCGA-VR-A8Q7-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8da6c8c1-2c10-42fe-9269-749686461e78

The open-access MAF lists 99 somatic variants for this specimen: 78 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 18, Frame Shift Del 5, Nonsense Mutation 5, Splice Site 3, Intron 2, Splice Region 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 22/41 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANXA11 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55418036; called by muse, mutect2
- BBX | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs76764171; called by muse, mutect2, varscan2
- CADM1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100522807; called by muse, mutect2, varscan2
- DCAF17 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59830460; called by muse, mutect2, varscan2
- DGKB | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as COSV99336557; called by muse, mutect2, varscan2
- DNAH5 | c.3760C>G p.R1254G | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV54237035; called by muse, mutect2, varscan2
- FRMPD4 | c.1870A>G p.S624G | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV101043163; called by muse, mutect2
- GRIA2 | c.1130A>C p.E377A | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV52381621; called by muse, mutect2, varscan2
- HK3 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750375133, COSV52841302; called by muse, mutect2, varscan2
- IGHV1-3 | c.341A>C p.Y114S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs544941582; called by muse, mutect2
- IL22RA1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as rs777028986, COSV54628166; called by muse, mutect2, varscan2
- KIRREL1 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs778661101, COSV63286019; called by muse, mutect2, varscan2
- LIFR | c.2107G>T p.G703* | Nonsense Mutation (SNP) | VAF 15/149 reads (10%) | catalogued as COSV54686491, COSV99665753; called by muse, mutect2, varscan2
- OR8G5 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.125); catalogued as rs773370353, COSV100422585, COSV100422694; called by muse, mutect2, varscan2
- PRAMEF6 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1322923054, COSV100755884, COSV100755925; called by muse, mutect2, varscan2
- RSPH10B | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs749914563; called by muse, mutect2, varscan2
- SACS | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs373613604; called by muse, mutect2, varscan2
- SERPINB11 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs769803949; called by muse, mutect2
- SLC8A2 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1568445831; called by muse, mutect2, varscan2
- SMARCA4 | c.4333C>T p.R1445W | Missense Mutation (SNP) | VAF 94/141 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775399739, COSV60785568; called by muse, mutect2, varscan2
- TBX20 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.314); catalogued as COSV101282421; called by muse, mutect2, varscan2
- TMEM132E | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1183636597, COSV58699267; called by muse, mutect2, varscan2
- TMEM200C | c.59C>G p.P20R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV67309232; called by muse, mutect2, varscan2
- XKR4 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59325049; called by muse, mutect2, varscan2
- ABCA9 | c.3476A>C p.Y1159S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGAP1 | c.2426C>T p.A809V (on ENST00000304032 / NM_001037131.3; = p.A756V on NM_014914.5) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AGTR2 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMPD2 | c.1956del p.N652Kfs*71 | Frame Shift Del (DEL) | VAF 23/114 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD23 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ANXA11 | c.1190A>T p.E397V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- ARHGAP28 | c.2096-1G>T p.X699_splice (on ENST00000383472 / NM_001366230.1; = p.X540_splice on NM_001010000.3) | Splice Site (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- ATP10B | c.1745A>T p.D582V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIRC6 | c.3630A>T p.K1210N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2
- CEBPZ | c.3133A>G p.T1045A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIC | c.237_240dup p.A81Cfs*4 | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- CNNM4 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CNOT2 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPED1 | c.1964A>G p.E655G | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.183); called by muse, mutect2
- CRYZL1 | c.476_497del p.T159Ifs*7 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- DCAF17 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- DHX8 | c.3472A>G p.T1158A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DROSHA | c.3217G>C p.D1073H | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2
- DUS3L | c.1084T>C p.F362L | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EMILIN3 | c.1739T>C p.L580P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EVL | c.893T>C p.M298T (on ENST00000402714 / NM_001330221.2; = p.M300T on NM_016337.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARP1 | c.1997G>C p.R666T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FMO3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FRAS1 | c.11410G>A p.D3804N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP2 | c.20326-25_20350del p.X6776_splice | Splice Site (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- FTO | c.1292G>C p.R431T | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GCFC2 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HGD | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ITGB4 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0319 | c.847A>G p.S283G | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LLGL1 | c.874A>G p.N292D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- LRRIQ1 | c.3196A>T p.I1066F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- LTBP1 | c.1517C>A p.P506Q (on ENST00000404816 / NM_206943.4; = p.P180Q on NM_000627.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MDGA2 | c.1300_1328del p.P434* (on ENST00000399232 / NM_001113498.2; = p.P136* on NM_182830.4) | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- NAV3 | c.741-1G>T p.X247_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- NPM1 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- OR5AR1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PARP4 | c.3578_3579del p.K1193Sfs*3 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- PCDHGB1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PHKA2 | c.1119C>G p.Y373* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | called by muse, varscan2
- PIKFYVE | c.653T>C p.L218S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- POLD1 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROS1 | c.2026T>A p.S676T | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO1A2 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SRGAP3 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SUN5 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBCEL | c.845C>G p.P282R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TIGD6 | c.725_728del p.H242Pfs*14 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by pindel, varscan2
- TOP2B | c.1318G>A p.A440T (on ENST00000264331 / NM_001330700.2; = p.A435T on NM_001068.3) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- TRAPPC9 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- TRPC1 | c.1581G>A p.Q527= (on ENST00000476941 / NM_001251845.2; = p.Q493= on NM_003304.4) | Splice Region (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- UNCX | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2
- ZBTB7A | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.197); called by muse, mutect2
- ACTA1 | c.1110C>A p.S370= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- ACTN3 | c.1086C>T p.S362= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- AGBL5 | c.123C>A p.A41= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- CCDC137 | c.96G>T p.L32= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- CLEC4A | c.6T>G p.T2= | Silent (SNP) | VAF 25/42 reads (60%) | called by muse, mutect2, varscan2
- CMYA5 | c.5877A>G p.Q1959= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- EPSTI1 | c.483A>G p.R161= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs150771459; called by muse, mutect2, varscan2
- FOXJ1 | c.606G>A p.A202= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs768447827; called by muse, mutect2, varscan2
- ILK | c.1272C>T p.L424= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- MYBPC3 | c.1801C>T p.L601= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- MYT1 | c.3231G>A p.P1077= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs149774713, COSV60510079; called by muse, mutect2
- NDST1 | c.108C>T p.Y36= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- RANBP1 | c.192C>G p.L64= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- S1PR1 | c.114C>T p.S38= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs777562427; called by muse, mutect2, varscan2
- SNED1 | c.1125C>T p.C375= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1173949099, COSV60023639; called by muse, mutect2
- TTN | c.77586C>A p.G25862= (on ENST00000591111; = p.G18438= on NM_003319.4) | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- ZFP14 | c.1122G>A p.G374= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- ZNF536 | c.1959C>T p.H653= | Silent (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504017 G>C | 5'Flank (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5382C>A | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- NRXN3 | c.602-5444T>C | Intron (SNP) | VAF 11/21 reads (52%) | catalogued as rs748740814; called by muse, mutect2, varscan2
